Somatic mutation profile of tumor specimen TCGA-XF-A9SV-01A (aliquot TCGA-XF-A9SV-01A-21D-A42E-08) from TCGA case TCGA-XF-A9SV, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 82.9 years (30,265 days).
Specimen TCGA-XF-A9SV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7299cc14-f144-41c4-b87d-f1afe86213bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-A9SV-10A (Blood Derived Normal), aliquot TCGA-XF-A9SV-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10f5e544-ec52-4da7-8619-c32dba2bd990

The open-access MAF lists 76 somatic variants for this specimen: 55 protein-altering or splice-affecting, 21 silent.
By variant classification: Missense Mutation 45, Silent 21, Splice Site 4, Nonsense Mutation 2, Splice Region 1, Translation Start Site 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 12/26 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- RFX6 | c.2596C>T p.R866* | Nonsense Mutation (SNP) | VAF 8/63 reads (13%) | catalogued as rs749827445, CM1512294, COSV100263268, COSV60584562; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1244G>A p.G415E (on ENST00000373993 / NM_138932.2; = p.G407E on NM_014576.4) | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.157); catalogued as COSV50966387; called by muse, mutect2, varscan2
- ACSM2B | c.724G>T p.A242S | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.027); catalogued as rs768259198, COSV61657972, COSV61659581; called by muse, mutect2, varscan2
- ACSM2B | c.723G>T p.K241N | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as COSV61659585; called by muse, mutect2, varscan2
- ADAM23 | c.720G>A p.E240= | Splice Region (SNP) | VAF 8/39 reads (21%) | catalogued as COSV52226939; called by muse, mutect2, varscan2
- ADCY8 | c.2350G>T p.A784S | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV53922839; called by muse, mutect2, varscan2
- ALG12 | c.1180G>A p.D394N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | PolyPhen probably damaging (0.983); catalogued as COSV58208200; called by muse, mutect2
- ANO3 | c.692G>A p.R231K | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT tolerated (1); PolyPhen possibly damaging (0.874); catalogued as COSV56805026; called by muse, mutect2, varscan2
- ARAP1 | c.1356C>G p.F452L (on ENST00000393609 / NM_001040118.2; = p.F207L on NM_015242.4) | Missense Mutation (SNP) | VAF 62/87 reads (71%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV61994194; called by muse, mutect2, varscan2
- ARL13A | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as COSV100879050, COSV65880330; called by muse, mutect2, varscan2
- BMS1 | c.1783G>A p.E595K | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV100996724; called by mutect2, varscan2
- CCDC102B | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as rs145012390, COSV60151373, COSV60151822; called by muse, mutect2, varscan2
- CDH11 | c.811A>T p.S271C | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV51773833; called by muse, mutect2, varscan2
- CDKL1 | c.658+1G>T p.X220_splice | Splice Site (SNP) | VAF 3/26 reads (12%) | catalogued as COSV99367562; called by muse, mutect2
- CNGB3 | c.478G>T p.A160S | Missense Mutation (SNP) | VAF 79/180 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as COSV60696482; called by muse, mutect2, varscan2
- DCC | c.767A>G p.D256G | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.082); catalogued as COSV59124784, COSV59128042; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2461G>A p.V821M | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs541647645, COSV62570217; called by muse, mutect2, varscan2
- FAM160A2 | c.212A>G p.N71S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV56414018; called by muse, mutect2, varscan2
- FEZF1 | c.1270G>A p.D424N | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV58659526; called by muse, mutect2, varscan2
- GOLGA4 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1560256713, COSV57887563; called by muse, mutect2, varscan2
- GPR89A | c.799G>T p.D267Y | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.594); catalogued as rs782797314, COSV100572464; called by muse, mutect2, varscan2
- GRM5 | c.2128G>T p.A710S | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV59623952; called by muse, mutect2, varscan2
- HYAL2 | c.1091A>G p.Y364C | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.375); catalogued as COSV63306771; called by muse, mutect2, varscan2
- IFNA5 | c.64C>G p.L22V | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV52387433; called by muse, mutect2, varscan2
- LILRB3 | c.1493C>A p.A498E (on ENST00000346401; = p.A486E on NM_006864.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV54444787; called by muse, mutect2, varscan2
- LONRF2 | c.921+1G>C p.X307_splice | Splice Site (SNP) | VAF 18/29 reads (62%) | catalogued as rs1337357436, COSV66540817, COSV66542022; called by muse, mutect2, varscan2
- MUC16 | c.12374C>T p.T4125M | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs577056863, COSV67471943; called by muse, mutect2, varscan2
- MYBL1 | c.816G>C p.E272D | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV72918707, COSV72919165; called by muse, mutect2, varscan2
- NTN1 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.948); catalogued as COSV51488314; called by muse, mutect2
- OPN1SW | c.875C>T p.S292F | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV50822973; called by muse, mutect2, varscan2
- OSBPL7 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as rs759528896, COSV50113774; called by muse, mutect2, varscan2
- PRKDC | c.8167A>C p.T2723P | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs371797273, COSV58049854; called by muse, mutect2, varscan2
- PSIP1 | c.815_816del p.T272Ifs*4 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | catalogued as COSV66255498; called by mutect2, pindel, varscan2
- PTPRT | c.2602G>A p.A868T | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs61753667, COSV61996547; called by muse, mutect2, varscan2
- RALB | c.67G>C p.G23R | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55603155, COSV55604583; called by muse, mutect2, varscan2
- RBM23 | c.532C>T p.R178W (on ENST00000359890 / NM_001077351.2; = p.R162W on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs774365880, COSV57128716; called by muse, mutect2, varscan2
- RIPPLY3 | c.452A>C p.K151T | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as rs1407531604, COSV100289363; called by muse, mutect2
- RYR1 | c.7076G>A p.R2359Q | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as rs1387126664, CM140866, COSV62091679, COSV62112838; ClinVar: uncertain significance; called by muse, mutect2
- SLC26A5 | c.1955T>G p.I652S | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV59705072; called by muse, mutect2, varscan2
- SOS1 | c.1046A>G p.H349R | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV67677262; called by muse, mutect2, varscan2
- SPHKAP | c.3230G>A p.R1077Q | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749393045, COSV60868686; called by muse, mutect2
- SPTAN1 | c.6945-2A>G p.X2315_splice | Splice Site (SNP) | VAF 20/29 reads (69%) | catalogued as COSV63989309; called by muse, mutect2, varscan2
- TBC1D1 | c.441C>G p.I147M | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV54717351, COSV54725547; called by muse, mutect2, varscan2
- TECR | c.86T>C p.I29T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs752066182, COSV53108953; called by muse, varscan2
- THSD7B | c.2101C>G p.R701G | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55726800, COSV55727651; called by muse, mutect2, varscan2
- TMED2 | c.167A>G p.D56G | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs1188523458, COSV51630067; called by muse, mutect2, varscan2
- TMEM214 | c.1791+2T>A p.X597_splice | Splice Site (SNP) | VAF 26/48 reads (54%) | catalogued as COSV53193746; called by muse, mutect2, varscan2
- ZNF383 | c.800C>G p.S267* | Nonsense Mutation (SNP) | VAF 12/66 reads (18%) | catalogued as COSV100776763; called by muse, mutect2, varscan2
- ZNF644 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as COSV61349832; called by muse, mutect2, varscan2
- ZP1 | c.1247C>A p.T416N | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.18); catalogued as COSV53926158; called by muse, mutect2, varscan2
- GPR89A | c.821G>A p.R274K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- IGHV3-64 | c.260G>A p.R87K | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- RPS6 | c.348dup p.G117Rfs*10 | Frame Shift Ins (INS) | VAF 14/50 reads (28%) | called by mutect2, varscan2
- TRBV4-1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- ADAMTS17 | c.2073C>T p.V691= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as COSV51491201; called by muse, mutect2, varscan2
- APBB1IP | c.1074G>A p.Q358= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV66135282; called by muse, mutect2, varscan2
- ATP10D | c.2898G>A p.Q966= | Silent (SNP) | VAF 44/78 reads (56%) | catalogued as rs1400838203, COSV56710851, COSV56712027; called by muse, mutect2, varscan2
- ATP5ME | c.147G>A p.K49= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as rs774192635, COSV55329770; called by muse, mutect2, varscan2
- CCDC40 | c.1860C>T p.G620= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs571288423, COSV66474618; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCNF | c.582G>C p.L194= | Silent (SNP) | VAF 19/100 reads (19%) | catalogued as COSV53542459; called by muse, mutect2, varscan2
- KCNN4 | c.57G>A p.L19= | Silent (SNP) | VAF 33/64 reads (52%) | catalogued as COSV53456843; called by muse, mutect2, varscan2
- KDM2A | c.21G>A p.R7= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as COSV67083629; called by muse, mutect2, varscan2
- KRT4 | c.1563G>A p.*521= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV53407609, COSV99542981; called by muse, mutect2, varscan2
- LRIT2 | c.219G>C p.G73= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV64518378, COSV64519700; called by muse, mutect2, varscan2
- NIPSNAP1 | c.576C>G p.L192= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as rs940586220, COSV53342808, COSV99331288; called by muse, mutect2, varscan2
- NPAS2 | c.2346C>T p.S782= | Silent (SNP) | VAF 19/36 reads (53%) | catalogued as COSV59561261; called by muse, mutect2, varscan2
- OR8I2 | c.540C>A p.T180= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as COSV56169936; called by muse, mutect2, varscan2
- PTGS2 | c.576G>A p.T192= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as rs200316914, COSV66571277; called by muse, mutect2, varscan2
- REG3A | c.441G>A p.A147= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as rs764024027, COSV59408168, COSV59409006; called by muse, mutect2, varscan2
- SON | c.4653T>C p.C1551= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs766895853, COSV51668340; called by muse, mutect2, varscan2
- UBXN1 | c.789C>T p.G263= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as COSV53658434, COSV99583465; called by muse, mutect2, varscan2
- VPS35 | c.1893C>T p.I631= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs1183192271, COSV54480727; called by muse, mutect2, varscan2
- ZFHX3 | c.7374G>A p.E2458= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV51731452; called by muse, mutect2, varscan2
- ZNF536 | c.579C>T p.R193= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV62821165, COSV62836290; called by muse, mutect2, varscan2
- ZNF765 | c.474G>A p.E158= | Silent (SNP) | VAF 84/157 reads (54%) | catalogued as COSV67183249; called by muse, mutect2, varscan2
